MMRF case MMRF_2402 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0a86f707-c49e-40cb-95d9-6b8f97ac7bc8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.9 years (25,884 days); ISS stage: II; Days to last known disease status: 787 days (2.2 years); Days to last follow up: 787 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 60 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.9 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 10.5 g/dL; Glucose 5.5 mmol/L.
- Day 82 (ECOG 0): M Protein 1.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 8.36 mmol/L.
- Day 176 (ECOG 1): M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 1.63 mmol/L; Albumin 30 g/L; Total Protein 5.2 g/dL; Glucose 4.13 mmol/L.
- Day 288 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 449 (ECOG 1): M Protein 1.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 5.28 mmol/L.
- Day 622 (ECOG 1): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 708 (ECOG 1): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.38 mmol/L.
- Day 787 (ECOG 1): M Protein 1.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day 1: Weight: 90 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2402_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2402_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
